Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EL, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EL-01A (Primary Tumor).

ICD-0-3
Melanoma, epithelioid
~~CSCF~~ 8721/3
Site: Cervical C69.3
^{path} Collocal tract C69.4
9/10 3/10/14

Macroscopy

Microscopy

The lesion is located at a large distance of the optic foramen and the optic nerve on its entire course and cut end is free of tumor. The tumor infiltrates all of the thickness of the sclera but there is no extra-scleral tumor extension. Presence of one intra-scleral endovascular tumor embolism. The ciliary body, the iris and the anterior chamber are free.

Epithelioid cells predominant.

Size of the tumor: 18 mm.

Tumor invasion of the sclera without extra-scleral extension.

Intra-scleral endovascular tumor embolism.

Optic nerve, ciliary body and anterior chamber free of tumor.

[illegible]

Source: NCI Genomic Data Commons file 2b8326f6-7742-472b-9973-f2e7171eebf2 (TCGA-V4-A9EL.036B1D86-3517-47E4-B285-BACE886AC434.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).